Somatic mutation profile of tumor specimen 0DJ8KR from CCDI case PBBWHN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.5 years (2,359 days).
Specimen 0DJ8KR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60a9dffe-544f-4cbe-ac95-c556d37146a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ8JK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45a0e8e2-b197-4448-a537-9e92bb3bf578

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HK1 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 266/756 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP11A | c.2797A>G p.K933E | Missense Mutation (SNP) | VAF 79/467 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1428756292; called by muse, mutect2, varscan2
- ARHGAP11A | c.2798A>T p.K933M | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV55707989; called by muse, varscan2
- TPRG1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 165/502 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs745626174, COSV61469277; called by muse, mutect2, varscan2
- ULK1 | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 211/1034 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); catalogued as rs202232188, COSV100416457; called by muse, mutect2, varscan2
- VAPB | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 181/632 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs989909629; called by muse, mutect2, varscan2
- ADGB | c.4431G>C p.L1477F | Missense Mutation (SNP) | VAF 184/798 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ERICH3 | c.3067T>C p.F1023L | Missense Mutation (SNP) | VAF 131/720 reads (18%) | SIFT tolerated, low confidence (0.7); called by muse, mutect2, varscan2
- IRF3 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 74/594 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KALRN | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 160/504 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- LPAR4 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 192/312 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- S100A7 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 45/1239 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- SORBS1 | c.3366A>T p.E1122D | Missense Mutation (SNP) | VAF 141/473 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1QC | c.675C>T p.Y225= | Silent (SNP) | VAF 129/769 reads (17%) | catalogued as rs748111761; called by muse, mutect2, varscan2
- IPPK | c.1215C>T p.I405= | Silent (SNP) | VAF 143/822 reads (17%) | catalogued as COSV99845862; called by muse, mutect2, varscan2
- LATS2 | c.1611C>T p.C537= | Silent (SNP) | VAF 108/620 reads (17%) | catalogued as rs748401705, COSV66873829; called by muse, mutect2, varscan2
- RMC1 | c.579T>C p.F193= | Silent (SNP) | VAF 197/744 reads (26%) | called by muse, mutect2, varscan2
- ZNF563 | c.801C>T p.S267= | Silent (SNP) | VAF 84/382 reads (22%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65214005 G>T | 3'Flank (SNP) | VAF 131/456 reads (29%) | called by muse, mutect2, varscan2
- IQCE | c.1608+39G>A | Intron (SNP) | VAF 75/392 reads (19%) | called by muse, mutect2, varscan2
- TNS2 | c.-93C>T | 5'UTR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
